Gene-level copy-number profile of tumor specimen TCGA-AC-A62X-01A from TCGA case TCGA-AC-A62X, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 72.9 years (26,627 days).
Specimen TCGA-AC-A62X-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.cdd09ef8-5842-49ac-a579-f71cd06ae41c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AC-A62X-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/dcc91df0-eb68-4b20-917f-19b6853b5cee

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 53; copy number 2: 13,362; copy number 3: 23,297; copy number 4: 8,513; copy number 5: 6,218; copy number 6: 1,632; copy number 7: 3,365; copy number 8: 2,357; copy number 9: 16; copy number 10: 398; copy number 11: 378; copy number 14: 90; copy number 15: 59; copy number 20: 74.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AC-A62X-01A-11D-A29M-01): tumor purity 0.79, ploidy 3.57, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 6,737 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–248,919,946, 2,604 genes, copy number 7 (broad region; genes not listed).
- chr6:18,522,735–138,344,663, 2,194 genes, copy number 8 (within-gene range 5–8) (broad region; genes not listed).
- chr8:100,475,667–104,256,094, 97 genes, copy number 7 (broad region; genes not listed).
- chr9:14,475–43,045,120, 776 genes, copy number 10–11 (broad region; genes not listed).
- chr10:52,230,398–91,284,337, 634 genes, copy number 7 (broad region; genes not listed).
- chr12:38,078,529–38,329,721, 11 genes, copy number 7: AK6P2, CLUHP8, AC079460.1, AC079460.2, RNA5SP358, RNA5SP359, TUBB8P5, AC117372.1, NF1P12, Y_RNA, ALG10B.
- chr12:39,447,404–40,570,832, 17 genes, copy number 7: AC121334.4, AC121334.1, AC121334.2, ABCD2, AC121334.3, C12orf40, SLC2A13, AC121336.1, RPL30P13, LINC02555, LINC02471, LRRK2-DT, LRRK2, AC084290.1, MUC19, AC107023.1, RNU6-713P.
- chr12:40,728,811–40,729,897, 1 gene, copy number 7: AC016144.1.
- chr12:44,008,620–44,010,143, 1 gene, copy number 7: ZNF75BP.
- chr14:22,163,238–26,598,033, 239 genes, copy number 9–20 (within-gene range 4–20) (broad region; genes not listed).
- chr21:10,328,411–22,520,058, 163 genes, copy number 8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 53. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
